Somatic mutation profile of tumor specimen MP2PRT-PARFZG-TMP1-A (aliquot MP2PRT-PARFZG-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARFZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,339 days).
Specimen MP2PRT-PARFZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 661fcfc5-0198-4da0-b339-52bef9f1a1e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARFZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARFZG-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d43a2f1-f652-4cdc-aaf8-b29b50108d71

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 34/401 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 59/466 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ENPP2 | c.1002A>T p.K334N (on ENST00000075322 / NM_001040092.3; = p.K386N on NM_006209.5) | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99309302; called by mutect2, varscan2
- EPB41L1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770202295, COSV52442601; called by muse, mutect2
- FAT4 | c.4525C>T p.R1509W | Missense Mutation (SNP) | VAF 52/568 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs200214434, COSV101272246, COSV67880799; called by muse, mutect2
- FLRT1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145808542; called by muse, mutect2, varscan2
- GNAI2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868958535, COSV56493406; called by muse, mutect2, varscan2
- KIR2DL1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 40/393 reads (10%) | catalogued as COSV99383459; called by muse, mutect2
- KLHL10 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 108/548 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs1238524455, COSV53174612; called by muse, mutect2, varscan2
- PRPF31 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 211/669 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774748387; called by muse, mutect2, varscan2
- RIMBP2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 134/450 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs769042353, COSV55483767; called by muse, mutect2, varscan2
- SCN9A | c.4864C>T p.R1622C (on ENST00000303354; = p.R1611C on NM_002977.3) | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270673434, COSV57622804; called by muse, mutect2
- TOP2B | c.2745C>A p.N915K (on ENST00000264331 / NM_001330700.2; = p.N910K on NM_001068.3) | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV51968451; called by muse, mutect2, varscan2
- TPRA1 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 33/407 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1422561324; called by muse, mutect2
- VPS16 | c.996G>A p.A332= | Splice Region (SNP) | VAF 37/376 reads (10%) | catalogued as rs199792133; called by muse, mutect2
- CRYGB | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ERFL | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- IGHV3-43 | c.353_354insCCCAC p.*119Pfs*? | Frame Shift Ins (INS) | VAF 60/292 reads (21%) | called by mutect2, varscan2
- PSMA1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2
- RGS7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 123/308 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RORB | c.122G>T p.C41F (on ENST00000396204 / NM_001365023.1; = p.C30F on NM_006914.4) | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5E | c.1326C>T p.Y442= | Silent (SNP) | VAF 53/586 reads (9%) | catalogued as rs368679446; called by muse, mutect2
- OCA2 | c.1758C>T p.L586= | Silent (SNP) | VAF 181/512 reads (35%) | catalogued as rs769393141, COSV62346777; called by muse, mutect2, varscan2
- ZNF862 | c.3423A>C p.A1141= | Silent (SNP) | VAF 18/678 reads (3%) | called by muse, mutect2
